MMRF case MMRF_2429 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/54321e01-7416-4d3f-ba95-904b40c8a97d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.0 years (25,566 days); ISS stage: II; Days to last known disease status: 776 days (2.1 years); Days to last follow up: 776 days (2.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 147 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 776.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 49.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 37.9 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.87 µg/mL; Lactate Dehydrogenase 6.07 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 8.6 g/dL; Glucose 5.23 mmol/L; C-Reactive Protein 0.058 mg/dL.
- Day 85 (ECOG 0): Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 530 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 5.9 g/dL; Glucose 4.13 mmol/L.
- Day 183: Hemoglobin 7.01 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 5.56 mmol/L.
- Day 253 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 9.62 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.56 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.68 mmol/L.
- Day 358 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 6.65 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.88 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 409 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.8 g/dL; Glucose 4.62 mmol/L.
- Day 443 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 4.99 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 6.13 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 359 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 5.28 mmol/L.
- Day 526 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 4.41 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.17 µg/mL; Lactate Dehydrogenase 8.05 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 305 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.3 g/dL; Glucose 5.34 mmol/L.
- Day 610 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 4.81 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 6.27 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 339 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 4.68 mmol/L.
- Day 736 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.09 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 0.473 g/L; Immunoglobulin M 0.172 g/L; Beta 2 Microglobulin 2.25 µg/mL; Hemoglobin 5.58 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.86 ×10⁹/L; Platelets 294 ×10⁹/L; Albumin 35 g/L; Total Protein 5.9 g/dL.

Other clinical attributes
- Day -6: Weight: 93 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Multiple Myeloma.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2429_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2429_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
